Surgical pathology report (de-identified scan), TCGA case TCGA-06-0125, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0125-02A (Recurrent Tumor).

Anatomic Pathology/Cytology Document State: (version)

Update Date/Time:
Final

Patient Name: MRN:
DOB/Age/Gender: Female Provider:
Location: Responsible Staff:

Service Date/Time:

PATH.NO:
NAME: MED. REC. NO:
AGE/SEX: F DOB: SURGERY DATE:
RECEIVE DATE:
PATIENT PHONE NO.:
PHYSICIAN:
COPY TO:

PATHOLOGICAL DIAGNOSIS:

- A. OCCIPITAL LOBE:
1. BENIGN CEBRAL CORTEX WITH MILD GLIOSIS.
2. UNREMARKABLE LEPTOMENINGES.
B. BRAIN TUMOR, BIOPSY: GLIOBLASTOMA MULTIFORME. (MIB: 15%)

Operation/Specimen: Occipital pole - FS.
Clinical History and Pre-Op Dx: H/O Crani for tumor
GROSS PATHOLOGY:
A. Occipital pole: Multiple tissue fragments, 0.4-0.6 cm.
INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Brain
parenchyma with gliosis. CASSETTES: 1, 2.
B. Brain tumor: Multiple 0.5-1.2 cm. tissue fragments.
INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioma.
CASSETTES: Glioma in cassette 3, remaining tissue in cassettes 4, 5.

MICROSCOPIC: A. Sections show well preserved cerebral cortex with
mild gliosis. No neoplasm present. The leptomeninges appears
unremarkable with no evidence of glioma cells. Immunostain for GFAP
confirms the absence of glioma cells in the leptomeninges.
B. Sections show high grade glioma with hypercellularity, vascularendothelial
hyperplasia and foci of necrosis. These changes are
consistent with recurrent glioma.

TISSUE COMMITTEE CODE:
ICD9: 191.2
BILLING CODES:

ICD-0-3 - recurrent
glioblastoma, multiforme 9440/3
Site: occipital pole C71.4

hw
11/12/15

Source: NCI Genomic Data Commons file fd85615e-fe0c-42af-add6-473c80311e86 (TCGA-06-0125.372DBF0F-48D7-457F-B1AB-C38287C61A35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).